Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q8, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q8-01A (Primary Tumor).

[page 1 of 2]
	lw 8/31/11	

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Thyroid nodule, FNA- PTC.

Specimens Submitted:

1: Pre-laryngeal lymph node

2: Total thyroid

DIAGNOSIS:

1. Pre-laryngeal lymph node:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

2. Total thyroid:

Tumor Type:

Papillary thyroid microcarcinoma

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 0.9 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

1CD-0-3

Path: Carcinoma, papillary, thyroid 8260/3

CQCF: Carcinoma, papillary, tall cell variant 8344/3

Site: thyroid, NOS C73.9

lw
8/31/11

[page 2 of 2]
Adenoma(s) (away from the carcinoma):

Not Identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not Identified

Lymph Nodes:

Two benign perithyroidal lymph nodes (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

M.D.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "prelaryngeal lymph node" and consists of a single firm lymph node measuring 0.7 x 0.5 x 0.3 cm. The lymph node is entirely submitted.

Summary of sections:

LN - lymph node

2). The specimen is received fresh, labeled "Total thyroid" and consists of a thyroid weighing 13.5 g. The right lobe measures 4.1 x 2.6 x 1.1 cm, the left lobe measures 4.2 x 2.5 x 1.8 cm and the isthmus measures 1.8 x 0.8 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 0.9 x 0.8 x 0.6 cm well circumscribed pink tan papillary nodule located in the left lower lobe approaching into the isthmus. The central portion is submitted for TPS, remaining nodule is blocked out and submitted. Sections through the remaining tissue reveal otherwise red tan grossly unremarkable parenchyma. Representative sections are submitted.

Summary of sections:

N - nodule (left lower lobe and isthmus)

RL - right lobe

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: Pre-laryngeal lymph node

Block	Sect. Site	PCs
1	U	1

Part 2: Total thyroid

Block	Sect. Site	PCs
1	IS	1
4	LL	4
3	N	3
4	RL	4

Source: NCI Genomic Data Commons file a9c00c6f-abb5-4456-8afc-1d09973a6852 (TCGA-DJ-A2Q8.52C74318-4B09-44FC-B813-4BD871E6742E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).